Gene-level copy-number profile of tumor specimen C3L-01557-01 from CPTAC case C3L-01557, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 51.1 years (18,652 days).
Specimen C3L-01557-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aa74c3e6-a595-4473-bbb9-e04bc74e7d8b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01557-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/59e60ca8-d6b2-4f73-9d38-0898e412a044

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 527; copy number 1: 12; copy number 2: 8,677; copy number 3: 330; copy number 4: 41,773; copy number 5: 42; copy number 6: 6,664; copy number 7: 78; copy number 8: 810; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,298,744–7,385,558, 7 genes: FAM66B, DEFB109B, USP17L1, USP17L4, AC130360.1, ZNF705G, DEFB108C.
- chr8:12,115,767–12,177,550, 6 genes (within-gene range 0–2): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr8:43,246,755–43,247,410, 2 genes: AC022616.5, AC022616.7.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:145,269,514–145,270,384, 1 gene, copy number 9: AC004911.1.

Autosomal genes at a single copy (total copy number 1): 8. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
